Somatic mutation profile of tumor specimen TCGA-14-0789-01A (aliquot TCGA-14-0789-01A-01W-0424-08) from TCGA case TCGA-14-0789, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.9 years (20,050 days).
Specimen TCGA-14-0789-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2b9f9e9-ad81-4f6f-addd-0c2cac96af71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-0789-10A (Blood Derived Normal), aliquot TCGA-14-0789-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3276f8ba-625d-44a2-9342-3ae895c1c80b

The open-access MAF lists 112 somatic variants for this specimen: 91 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Frame Shift Ins 36, Silent 20, Nonsense Mutation 5, Splice Site 2, In Frame Del 2, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.219dup p.R74Qfs*11 | Frame Shift Ins (INS) | VAF 48/389 reads (12%) | catalogued as rs398123489; ClinVar: pathogenic; called by mutect2, varscan2
- CNGB1 | c.2544dup p.L849Afs*3 | Frame Shift Ins (INS) | VAF 17/185 reads (9%) | catalogued as rs760430056; ClinVar: pathogenic; called by mutect2, pindel
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 56/360 reads (16%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 179/1096 reads (16%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.2848C>T p.Q950* | Nonsense Mutation (SNP) | VAF 73/338 reads (22%) | catalogued as rs1060500357, CM154908, COSV62201077; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.8136dup p.D2713Rfs*10 | Frame Shift Ins (INS) | VAF 9/97 reads (9%) | catalogued as rs761483896; ClinVar: pathogenic; called by mutect2, pindel
- STAT5B | c.1102dup p.Q368Pfs*9 | Frame Shift Ins (INS) | VAF 80/566 reads (14%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- ADSS1 | c.741dup p.K248Qfs*16 | Frame Shift Ins (INS) | VAF 18/141 reads (13%) | catalogued as rs769542442; called by mutect2, varscan2
- AKT1 | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.972); catalogued as COSV62572258; called by muse, mutect2, varscan2
- ALDH1A3 | c.849dup p.K284Efs*11 | Frame Shift Ins (INS) | VAF 23/187 reads (12%) | catalogued as rs758955164; called by mutect2, varscan2
- ASB15 | c.998A>G p.D333G | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51929596; called by muse, mutect2, varscan2
- AZGP1 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1335547800, COSV52799667; called by muse, mutect2, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 16/50 reads (32%) | catalogued as rs745882580; called by mutect2, varscan2
- BRSK1 | c.1135dup p.R379Pfs*54 | Frame Shift Ins (INS) | VAF 34/229 reads (15%) | catalogued as rs746043904; called by mutect2, varscan2
- CACNA2D3 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 168/609 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs775275975, COSV55510818; called by muse, mutect2, varscan2
- CALN1 | c.569G>A p.R190Q (on ENST00000329008 / NM_001017440.3; = p.R232Q on NM_031468.4) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767122514, COSV61147636; called by muse, mutect2, varscan2
- CCDC158 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV66357296; called by muse, mutect2, varscan2
- CCS | c.285dup p.P96Afs*16 | Frame Shift Ins (INS) | VAF 10/84 reads (12%) | catalogued as rs759691599; called by mutect2, varscan2
- CDX2 | c.916dup p.V306Gfs*31 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | catalogued as rs773511514; called by mutect2, varscan2
- CHD3 | c.1618dup p.R540Pfs*47 | Frame Shift Ins (INS) | VAF 38/326 reads (12%) | catalogued as rs747299117; called by mutect2, varscan2
- CHD5 | c.3484G>T p.A1162S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV52426017; called by muse, mutect2, varscan2
- CHL1 | c.1531A>T p.I511F (on ENST00000397491 / NM_001253387.1; = p.I527F on NM_006614.4) | Missense Mutation (SNP) | VAF 94/317 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56607695; called by muse, mutect2, varscan2
- CIT | c.5422G>A p.G1808R | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55884446; called by muse, mutect2, varscan2
- CNTN2 | c.2438G>T p.R813M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.195); catalogued as COSV59353439; called by muse, mutect2
- DMXL2 | c.4364G>A p.S1455N | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.053); catalogued as rs780394765, COSV104377885; called by muse, mutect2
- EGFR | c.1883G>A p.C628Y | Missense Mutation (SNP) | VAF 745/6926 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51840469, COSV51851464; called by muse, mutect2, varscan2
- EPHB6 | c.849dup p.R284Qfs*41 | Frame Shift Ins (INS) | VAF 17/148 reads (11%) | catalogued as rs145544148; called by mutect2, varscan2
- FGA | c.1284C>A p.Y428* | Nonsense Mutation (SNP) | VAF 133/364 reads (37%) | catalogued as COSV57401687; called by muse, mutect2, varscan2
- FLG2 | c.1166A>C p.Q389P | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.315); catalogued as COSV66173898; called by muse, mutect2, varscan2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 12/94 reads (13%) | catalogued as rs752538869; called by mutect2, varscan2
- GCNT4 | c.880dup p.H294Pfs*2 | Frame Shift Ins (INS) | VAF 39/363 reads (11%) | catalogued as rs768450027; called by mutect2, varscan2
- GNAZ | c.612dup p.Q205Afs*35 | Frame Shift Ins (INS) | VAF 37/244 reads (15%) | catalogued as rs752075537; called by mutect2, varscan2
- GPRC6A | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs368860950, COSV59956215; called by muse, mutect2, varscan2
- GPSM2 | c.1955G>C p.R652T | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.253); catalogued as COSV51440771, COSV51444810; called by muse, mutect2, varscan2
- GRM3 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 72/325 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64467183, COSV64474717; called by muse, mutect2, varscan2
- HARS1 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 240/744 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1295541335, COSV56909238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HHIPL2 | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 30/73 reads (41%) | catalogued as rs778287202, COSV58565046; called by muse, mutect2, varscan2
- HPCAL4 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV65716398; called by muse, mutect2, varscan2
- INAVA | c.67dup p.E23Gfs*11 | Frame Shift Ins (INS) | VAF 5/20 reads (25%) | catalogued as rs750421792; called by mutect2, pindel
- IRS4 | c.1772dup p.K592Qfs*12 | Frame Shift Ins (INS) | VAF 31/145 reads (21%) | catalogued as rs780982673; called by mutect2, varscan2
- ISG20L2 | c.865dup p.L289Pfs*6 | Frame Shift Ins (INS) | VAF 20/90 reads (22%) | catalogued as rs761558950; called by mutect2, varscan2
- ITPR3 | c.1420C>T p.Q474* | Nonsense Mutation (SNP) | VAF 193/781 reads (25%) | catalogued as COSV65415278; called by muse, mutect2, varscan2
- KLHL42 | c.1194dup p.C399Vfs*43 | Frame Shift Ins (INS) | VAF 7/42 reads (17%) | catalogued as rs749194179; called by mutect2, varscan2
- LDLR | c.1514G>C p.G505A | Missense Mutation (SNP) | VAF 230/1032 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as CM023641, COSV52946222; called by muse, mutect2, varscan2
- LPA | c.3287+1G>A p.X1096_splice | Splice Site (SNP) | VAF 372/1279 reads (29%) | catalogued as rs767906902, COSV60309190; called by muse, mutect2, varscan2
- LRP1 | c.2814dup p.N939Qfs*18 | Frame Shift Ins (INS) | VAF 18/152 reads (12%) | catalogued as rs750932259; called by mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 48/241 reads (20%) | catalogued as rs757410385; called by mutect2, varscan2
- LRP1B | c.12446A>G p.E4149G | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as COSV67278893; called by muse, mutect2, varscan2
- LRP4 | c.5504dup p.L1836Pfs*24 | Frame Shift Ins (INS) | VAF 14/100 reads (14%) | catalogued as rs745628337; called by mutect2, varscan2
- NCOA5 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs777887637, COSV51645044; called by muse, mutect2, varscan2
- NRXN2 | c.808dup p.A270Gfs*27 | Frame Shift Ins (INS) | VAF 43/189 reads (23%) | catalogued as rs754860965; called by mutect2, varscan2
- OR52D1 | c.286T>A p.S96T | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV59488427; called by muse, mutect2, varscan2
- PAN3 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 174/543 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs775770672, COSV66707094; called by muse, mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 68/616 reads (11%) | catalogued as rs749506841; called by mutect2, varscan2
- PIK3CB | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 95/373 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV56690646; called by muse, mutect2, varscan2
- PLB1 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs149462466; called by muse, mutect2, varscan2
- PLOD3 | c.876dup p.Q293Afs*48 | Frame Shift Ins (INS) | VAF 24/164 reads (15%) | catalogued as rs746342377; called by mutect2, varscan2
- POF1B | c.133A>C p.K45Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.22); catalogued as COSV53135663; called by muse, mutect2, varscan2
- PRCC | c.1138dup p.Q380Pfs*12 | Frame Shift Ins (INS) | VAF 46/320 reads (14%) | catalogued as rs778683789; called by mutect2, varscan2
- PRIMA1 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.801); catalogued as rs200260569, COSV60264799, COSV60265016; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRA | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs773334274, COSV53780647; called by muse, mutect2, varscan2
- RAG1 | c.1743G>A p.M581I | Missense Mutation (SNP) | VAF 38/1570 reads (2%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); catalogued as COSV55027409; called by muse, mutect2
- RALGAPB | c.1142dup p.H382Tfs*2 | Frame Shift Ins (INS) | VAF 16/122 reads (13%) | catalogued as rs756557178; called by mutect2, varscan2
- RYR2 | c.7027C>T p.L2343F | Missense Mutation (SNP) | VAF 134/402 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63705227, COSV63717015; called by muse, mutect2, varscan2
- RYR3 | c.106T>A p.F36I | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV66809676; called by muse, mutect2, varscan2
- SETD7 | c.1026dup p.G343Rfs*6 | Frame Shift Ins (INS) | VAF 18/164 reads (11%) | catalogued as rs35259575; called by mutect2, varscan2
- SGO2 | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as COSV63418414; called by muse, mutect2, varscan2
- SHC1 | c.1087dup p.V363Gfs*61 (on ENST00000368445 / NM_183001.5; = p.V253Gfs*62 on NM_003029.5) | Frame Shift Ins (INS) | VAF 66/376 reads (18%) | catalogued as rs746556543; called by mutect2, varscan2
- SLC6A18 | c.634A>C p.T212P | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777600288; called by muse, mutect2
- SP140 | c.643A>T p.S215C | Missense Mutation (SNP) | VAF 105/351 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.887); catalogued as COSV59454477; called by muse, mutect2, varscan2
- TEAD2 | c.883dup p.H295Pfs*19 | Frame Shift Ins (INS) | VAF 68/416 reads (16%) | catalogued as rs763321097; called by mutect2, varscan2
- THBS4 | c.2863A>G p.N955D | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV63471106; called by muse, mutect2, varscan2
- TLR10 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs375480992; called by muse, mutect2, varscan2
- VEGFA | c.433C>T p.R145* (on ENST00000523873 / NM_001171623.1; = p.R325* on NM_003376.6) | Nonsense Mutation (SNP) | VAF 83/266 reads (31%) | catalogued as rs45533131, CM119370, COSV57879341; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF10 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV50212174; called by mutect2, varscan2
- ZP2 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as rs766836952, COSV54817102; called by muse, mutect2, varscan2
- ZRSR2 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as COSV57067781; called by muse, mutect2, varscan2
- ESYT1 | c.84dup p.A29Rfs*22 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by pindel, varscan2
- FKBP10 | c.920A>C p.Y307S | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- FNBP4 | c.2568G>T p.M856I | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2
- KAT2A | c.665G>A p.G222D | Missense Mutation (SNP) | VAF 22/426 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.521); called by muse, mutect2
- MCF2L2 | c.561dup p.T188Dfs*66 | Frame Shift Ins (INS) | VAF 9/91 reads (10%) | called by mutect2, pindel
- RAD51AP2 | c.741del p.K247Nfs*11 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- RYR2 | c.9095G>C p.C3032S | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2
- SCYL1 | c.850_862del p.X284_splice | Splice Site (DEL) | VAF 168/680 reads (25%) | called by mutect2*, pindel
- SLC38A6 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 9/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STAG2 | c.442dup p.M148Nfs*3 | Frame Shift Ins (INS) | VAF 22/44 reads (50%) | called by mutect2, pindel, varscan2
- THOC2 | c.4332_4334del p.P1446del | In Frame Del (DEL) | VAF 14/37 reads (38%) | called by pindel, varscan2
- TSPOAP1 | c.221dup p.T75Nfs*2 | Frame Shift Ins (INS) | VAF 3/26 reads (12%) | called by pindel, varscan2
- ZNF512B | c.666G>T p.M222I | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2
- ZNF546 | c.2479_2481del p.H827del | In Frame Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- ABCB4 | c.216C>A p.P72= | Silent (SNP) | VAF 130/632 reads (21%) | catalogued as rs746750803, COSV55942367; called by mutect2, varscan2
- ACVRL1 | c.1152G>A p.Q384= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV66361246; called by muse, mutect2, varscan2
- DBH | c.639C>T p.T213= | Silent (SNP) | VAF 91/265 reads (34%) | catalogued as COSV55042495, COSV99708017; called by muse, mutect2, varscan2
- ESPL1 | c.6300C>T p.P2100= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as COSV54477209; called by muse, mutect2, varscan2
- GABRB3 | c.1200C>A p.I400= | Silent (SNP) | VAF 91/284 reads (32%) | catalogued as COSV54683557, COSV54685401; called by muse, mutect2, varscan2
- GIPC1 | c.339G>C p.L113= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV61775127; called by muse, mutect2, varscan2
- HMCN1 | c.8814C>A p.I2938= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV54944881; called by muse, mutect2, varscan2
- LINGO4 | c.786C>T p.C262= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs769036572, COSV63216824; called by muse, mutect2, varscan2
- MRTO4 | c.477C>T p.P159= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs1238626382, COSV57673190, COSV57674725; called by muse, mutect2
- PCDHA2 | c.201G>A p.A67= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs782585524, COSV65371264; called by muse, mutect2, varscan2
- PDE4DIP | c.3030G>A p.R1010= | Silent (SNP) | VAF 121/404 reads (30%) | catalogued as rs782507477, COSV57699079, COSV57731045; called by muse, mutect2, varscan2
- PRMT3 | c.987G>A p.E329= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV58181161; called by muse, mutect2
- PRRT1 | c.543C>T p.V181= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs947118282, COSV52999707; called by muse, mutect2, varscan2
- S100A7A | c.102G>A p.T34= | Silent (SNP) | VAF 90/377 reads (24%) | catalogued as rs370692845; called by muse, mutect2, varscan2
- TLR7 | c.654C>T p.A218= | Silent (SNP) | VAF 317/468 reads (68%) | catalogued as rs201282415, COSV101027829, COSV66124680; called by muse, mutect2, varscan2
- TMPRSS4 | c.1038G>A p.A346= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as rs764161015, COSV71109553; called by muse, mutect2, varscan2
- TRIP11 | c.3639G>A p.K1213= | Silent (SNP) | VAF 51/229 reads (22%) | catalogued as COSV50966098, COSV50973458; called by muse, mutect2, varscan2
- TSKS | c.1653C>T p.H551= | Silent (SNP) | VAF 48/200 reads (24%) | catalogued as COSV55879857, COSV99883537; called by muse, varscan2
- UGT1A10 | c.27C>T p.P9= | Silent (SNP) | VAF 124/384 reads (32%) | catalogued as rs1322999911, COSV60853075; called by muse, mutect2, varscan2
- ZNF532 | c.2235C>T p.D745= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV60175998; called by muse, mutect2, varscan2
- MATN4 | chr20:45308174 C>A | 5'Flank (SNP) | VAF 5/26 reads (19%) | catalogued as COSV59215982; called by muse, mutect2, varscan2
